Gene-level copy-number profile of tumor specimen MP2PRT-PARFIZ-TMP1-A from MP2PRT case MP2PRT-PARFIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,621 days).
Specimen MP2PRT-PARFIZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1e37a8b-9ab4-45cd-b34c-a93b1ceccd6f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARFIZ-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/2760214f-214d-492c-b8bd-5c7544f8384a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 199; copy number 2: 48,620; copy number 3: 6,574; copy number 4: 2,988.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,078,010–89,085,787, 2 genes (within-gene range 0–1): IGKV2-14, IGKV3-15.
- chr2:89,170,775–89,192,752, 4 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr7:38,253,380–38,256,396, 2 genes (within-gene range 0–1): TRGJ2, TRGJP2.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
